Somatic mutation profile of tumor specimen 3bbf4310-6a83-4d3b-8772-a5dbb6 (aliquot 3bbf4310-6a83-4d3b-8772-a5dbb6_D6_1) from CPTAC case 18BR016, project CPTAC-2 (Breast — Ductal and Lobular Neoplasms). Sex at birth: female; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IA; Age at diagnosis: 73.7 years (26,918 days).
Specimen 3bbf4310-6a83-4d3b-8772-a5dbb6: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 405ec35a-fda8-4344-af2e-9e3c1cf7868f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 4720de03-4a0e-4574-99c2-7fd6dc (Blood Derived Normal), aliquot 4720de03-4a0e-4574-99c2-7fd6dc_D1_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fe30e4c6-b17d-4776-b230-2625cc084bfd

The open-access MAF lists 50 somatic variants for this specimen: 36 protein-altering or splice-affecting, 9 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 29, Silent 9, Frame Shift Del 4, Splice Site 2, 3'UTR 2, RNA 2, Frame Shift Ins 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.2702G>T p.C901F | Missense Mutation (SNP) | VAF 11/51 reads (22%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55881149; called by muse, mutect2, varscan2
- PTEN | c.744del p.V249Cfs*7 | Frame Shift Del (DEL) | VAF 60/270 reads (22%) | catalogued as rs1554825224; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- ADAMTS3 | c.1921+1G>A p.X641_splice | Splice Site (SNP) | VAF 38/145 reads (26%) | catalogued as rs753688774; called by muse, mutect2, varscan2
- DPP7 | c.368G>T p.R123L | Missense Mutation (SNP) | VAF 5/79 reads (6%) | SIFT tolerated (0.35); PolyPhen benign (0.003); catalogued as COSV65371221; called by muse, mutect2
- GPR68 | c.191C>T p.T64M | Missense Mutation (SNP) | VAF 63/279 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs752894280; called by muse, mutect2, varscan2
- GZMM | c.211C>T p.R71W | Missense Mutation (SNP) | VAF 17/76 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.933); catalogued as rs1408535175, COSV52742350; called by muse, mutect2, varscan2
- MAML3 | c.244G>A p.E82K | Missense Mutation (SNP) | VAF 181/671 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs931430833, COSV72210183; called by muse, mutect2, varscan2
- MED23 | c.1037T>G p.F346C | Missense Mutation (SNP) | VAF 85/323 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as COSV63436610; called by muse, mutect2, varscan2
- P2RY4 | c.434G>A p.R145H | Missense Mutation (SNP) | VAF 30/470 reads (6%) | SIFT tolerated (0.27); PolyPhen benign (0.019); catalogued as rs768553391; called by muse, mutect2
- PTEN | c.955_958del p.T319* | Frame Shift Del (DEL) | VAF 48/173 reads (28%) | catalogued as rs146650273; called by pindel, varscan2
- R3HCC1 | c.436G>A p.G146S (on ENST00000411463; = p.G106S on NM_001136108.3) | Missense Mutation (SNP) | VAF 35/282 reads (12%) | SIFT tolerated (0.13); PolyPhen benign (0.007); catalogued as rs555802428; called by muse, mutect2, varscan2
- RGMB | c.437G>T p.G146V (on ENST00000513185 / NM_001366508.1; = p.G187V on NM_001012761.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 69/263 reads (26%) | SIFT tolerated (0.28); PolyPhen benign (0.193); catalogued as rs1407074072; called by muse, mutect2, varscan2
- RRP15 | c.592C>T p.R198C | Missense Mutation (SNP) | VAF 12/195 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.21); catalogued as rs546410420, COSV65118156; called by muse, mutect2
- SLCO6A1 | c.1049G>A p.R350H | Missense Mutation (SNP) | VAF 17/63 reads (27%) | SIFT tolerated (0.22); PolyPhen benign (0.288); catalogued as rs201223529; called by muse, mutect2, varscan2
- SOX9 | c.810C>A p.F270L | Missense Mutation (SNP) | VAF 106/381 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.079); catalogued as COSV55428777; called by muse, mutect2, varscan2
- THRA | c.989C>G p.S330W | Missense Mutation (SNP) | VAF 54/178 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV52846460; called by muse, mutect2, varscan2
- ZNF543 | c.691G>A p.E231K | Missense Mutation (SNP) | VAF 48/363 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV58627332, COSV58627459; called by muse, mutect2, varscan2
- ZSCAN10 | c.1787G>A p.R596H (on ENST00000252463; = p.R651H on NM_032805.3) | Missense Mutation (SNP) | VAF 54/342 reads (16%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.968); catalogued as COSV99373902; called by muse, varscan2
- AHNAK | c.2803A>G p.K935E | Missense Mutation (SNP) | VAF 43/168 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.452); called by muse, mutect2, varscan2
- ALMS1 | c.1310G>T p.S437I | Missense Mutation (SNP) | VAF 30/272 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.843); called by muse, mutect2, varscan2
- AWAT2 | c.713C>T p.P238L | Missense Mutation (SNP) | VAF 15/405 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.198); called by muse, mutect2
- AWAT2 | c.712C>T p.P238S | Missense Mutation (SNP) | VAF 15/406 reads (4%) | SIFT tolerated (0.1); PolyPhen benign (0.023); called by muse, mutect2
- CCDC17 | c.1360A>G p.I454V | Missense Mutation (SNP) | VAF 47/159 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- CCDC73 | c.2509C>T p.H837Y | Missense Mutation (SNP) | VAF 36/128 reads (28%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.77); called by muse, mutect2, varscan2
- DNAJB12 | c.1036del p.T346Qfs*94 (on ENST00000338820; = p.T312Qfs*77 on NM_017626.6 and 3 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 24/142 reads (17%) | called by mutect2, pindel, varscan2
- DYSF | c.458-1G>C p.X153_splice | Splice Site (SNP) | VAF 116/445 reads (26%) | called by muse, mutect2, varscan2
- FSIP2 | c.1646C>T p.S549F | Missense Mutation (SNP) | VAF 21/181 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- KDM2A | c.2024dup p.C675Wfs*19 | Frame Shift Ins (INS) | VAF 15/68 reads (22%) | called by mutect2, pindel, varscan2
- MED29 | c.539_542del p.Q180Pfs*61 (on ENST00000615911; = p.Q159Pfs*61 on NM_017592.4) | Frame Shift Del (DEL) | VAF 129/465 reads (28%) | called by mutect2, pindel, varscan2
- MYNN | c.1102G>T p.A368S | Missense Mutation (SNP) | VAF 22/58 reads (38%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- NCOA1 | c.2207A>T p.D736V | Missense Mutation (SNP) | VAF 49/186 reads (26%) | SIFT tolerated (0.32); PolyPhen benign (0.107); called by muse, mutect2, varscan2
- NPAS4 | c.19G>A p.G7S | Missense Mutation (SNP) | VAF 9/154 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2
- SLC2A9 | c.1288C>G p.P430A | Missense Mutation (SNP) | VAF 9/197 reads (5%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.997); called by muse, mutect2
- SLMAP | c.1931G>A p.G644E (on ENST00000428312 / NM_001377924.1; = p.G706E on NM_007159.5) | Missense Mutation (SNP) | VAF 12/145 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2
- SOX9 | c.809T>A p.F270Y | Missense Mutation (SNP) | VAF 104/380 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.341); called by muse, mutect2, varscan2
- USH2A | c.3146G>A p.G1049D | Missense Mutation (SNP) | VAF 111/766 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- CELSR3 | c.4185C>G p.R1395= | Silent (SNP) | VAF 79/243 reads (33%) | called by muse, mutect2, varscan2
- DNAH2 | c.2172C>G p.A724= | Silent (SNP) | VAF 13/90 reads (14%) | catalogued as rs777190654; called by muse, mutect2, varscan2
- LRATD2 | c.393G>T p.P131= | Silent (SNP) | VAF 111/395 reads (28%) | called by muse, mutect2, varscan2
- MYLK2 | c.606G>A p.E202= | Silent (SNP) | VAF 36/244 reads (15%) | called by muse, mutect2, varscan2
- PAPPA | c.1386C>T p.N462= | Silent (SNP) | VAF 63/288 reads (22%) | catalogued as rs548115666; called by muse, mutect2, varscan2
- PDE12 | c.1248G>A p.E416= | Silent (SNP) | VAF 28/180 reads (16%) | called by muse, mutect2, varscan2
- TBX1 | c.1047G>A p.E349= | Silent (SNP) | VAF 36/300 reads (12%) | called by muse, mutect2, varscan2
- TRIOBP | c.2112C>T p.D704= | Silent (SNP) | VAF 44/230 reads (19%) | catalogued as rs533171349, COSV100730842; called by muse, mutect2, varscan2
- ZBTB14 | c.519T>G p.P173= | Silent (SNP) | VAF 69/230 reads (30%) | called by muse, mutect2, varscan2
- CNNM3 | c.*331G>A | 3'UTR (SNP) | VAF 15/161 reads (9%) | catalogued as rs542024412; called by muse, mutect2
- LINC01001 | n.484G>C | RNA (SNP) | VAF 8/62 reads (13%) | catalogued as rs61869653; called by muse, mutect2, varscan2
- LITAF | c.*1154G>A | 3'UTR (SNP) | VAF 8/76 reads (11%) | catalogued as COSV59654943; called by muse, mutect2, varscan2
- MIR600 | n.26C>T | RNA (SNP) | VAF 13/86 reads (15%) | called by muse, mutect2, varscan2
- PABPN1 | c.352-36T>G | Intron (SNP) | VAF 83/342 reads (24%) | called by muse, mutect2, varscan2
